Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7Z4, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7Z4-01A (Primary Tumor).

Patient: [REDACTED]

Surgical Pathology: Final

Acc#: [REDACTED]

Surg Path

ICD-O-3

Astrocytoma, grade II 9400/3
Site: ~~left~~ Brain, supratentorial NOS C71.0
~~right~~ Brain NOS C71.9

CLINICAL HISTORY:
Brain tumor.

GROSS EXAMINATION:

A. "Brain tumor (AF1)", received fresh for frozen section. A 2.0 x 2.0 x 1.0 cm aggregate of multiple fragments of soft tan tissue is received. Representative fragment frozen as AF1 and frozen section remnant is submitted in A1. A representative fragment is retained in formalin. The remainder of the tissue is submitted in A2.

B. "Brain tumor", received fresh and placed in formalin. A 4.0 x 3.8 x 2.0 cm aggregate of multiple fragments of pink/tan tissue is received. Representative sections are submitted in [REDACTED]. The remainder of the tissue is retained in formalin.

INTRA OPERATIVE CONSULTATION:

A. "Brain tumor": AF1 - glioma, grade deferred (Dr.

MICROSCOPIC EXAMINATION:

The specimen is brain tissue which is infiltrated by a glial neoplasm. There is a prominent microcystic component, and readily found microcalcifications. In general, the nuclei are round and regular, some of which exhibit perinuclear haloes. Some cells contain a small quantity of eosinophilic cytoplasm typical of mini gemistocytes. Focally, there are areas of increased cellularity, in which the nuclei are more elongated and contain hyperchromatic nuclei. Although there is no unequivocal vascular proliferation, in some areas the blood vessels are thickened and appear to have prominent endothelium. Necrosis is not identified, and mitotic figures are not definitively encountered. Although some of this neoplasm exhibits features suggestive of an oligodendroglioma, the hypercellular areas with hyperchromatic and elongated nuclei are more suggestive of astrocytic differentiation.

IMMUNOHISTOCHEMICAL FINDINGS:

The KI-67 (proliferation antigen) labeling index focally approaches 5%.

DIAGNOSIS:

A. "BRAIN TUMOR":

WELL DIFFERENTIATED ASTROCYTOMA (WHO GRADE II). SEE COMMENT.

B. "BRAIN TUMOR":

WELL DIFFERENTIATED ASTROCYTOMA (WHO GRADE II). SEE COMMENT.

COMMENT: Although the majority of this neoplasm has features of a low grade tumor, the foci of increased cellularity and mild elevation of the MIB-1 labeling index may portend more aggressive behavior. Close clinical follow-up is recommended.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

IIIFAA Discrepancy		☒

Source: NCI Genomic Data Commons file f2370395-fa40-465f-bba5-77b768036933 (TCGA-E1-A7Z4.670D1EE5-1ACF-418C-8A4E-B669D12D54AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).